Somatic mutation profile of tumor specimen TCGA-HF-7136-01A (aliquot TCGA-HF-7136-01A-11D-2053-08) from TCGA case TCGA-HF-7136, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2.
Specimen TCGA-HF-7136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75c9a2b9-1686-45ce-b66f-7faf034f80cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-7136-10A (Blood Derived Normal), aliquot TCGA-HF-7136-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d46cb779-7296-4d7b-b030-ca2637b0620d

The open-access MAF lists 84 somatic variants for this specimen: 67 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Frame Shift Del 6, Frame Shift Ins 3, Nonsense Mutation 2, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 54/105 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, mutect2, varscan2
- ADCY8 | c.3248A>T p.N1083I | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53920290; called by muse, mutect2, varscan2
- ADGRE2 | c.31+2T>C p.X11_splice | Splice Site (SNP) | VAF 15/15 reads (100%) | catalogued as COSV59695465; called by muse, mutect2, varscan2
- ADGRL4 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs547554975, COSV66064053; called by muse, mutect2, varscan2
- ANK3 | c.798G>C p.R266S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55073414; called by muse, mutect2, varscan2
- ATXN2 | c.2713G>T p.A905S (on ENST00000550104; = p.A745S on NM_002973.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as COSV66484938, COSV66485229; called by muse, varscan2
- C12orf4 | c.1496A>T p.K499I | Missense Mutation (SNP) | VAF 96/130 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54208725; called by muse, mutect2, varscan2
- CASP1 | c.760G>C p.D254H (on ENST00000436863 / NM_033292.4; = p.D233H on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62057245; called by muse, mutect2, varscan2
- CDKN2A | c.334del p.R112Vfs*34 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as CM013695, COSV58684425, COSV58709681, COSV58723857; called by mutect2, pindel, varscan2
- CLTCL1 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.98); PolyPhen benign (0.02); catalogued as COSV54236289; called by muse, mutect2, varscan2
- CPS1 | c.2258T>C p.V753A | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51819413; called by muse, mutect2
- CSNK1A1L | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as rs1396915431, COSV65789478; called by muse, mutect2, varscan2
- CYLC1 | c.726T>G p.S242R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV61414507; called by muse, varscan2
- DMRTB1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV65112999; called by muse, mutect2, varscan2
- DNAH10 | c.5092G>A p.V1698M (on ENST00000409039; = p.V1637M on NM_207437.3) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369082437; called by muse, mutect2, varscan2
- EEF2K | c.1736A>T p.H579L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53785332; called by muse, mutect2, varscan2
- ETV7 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775769716, COSV60317370; called by muse, mutect2
- FCRLB | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.811); catalogued as rs147870526; called by muse, mutect2, varscan2
- FOXS1 | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as rs1424699133, COSV54067682; called by muse, mutect2, varscan2
- GATA6 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV52525683; called by muse, mutect2
- GBF1 | c.2236C>T p.R746W (on ENST00000369983 / NM_001377137.1; = p.R745W on NM_004193.3) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs748525369, COSV64147616; called by muse, mutect2, varscan2
- GEMIN2 | c.599A>C p.N200T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV51629181; called by muse, mutect2, varscan2
- HAUS6 | c.1474A>C p.N492H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.66); catalogued as COSV65840521; called by muse, mutect2, varscan2
- HERC4 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV53273925; called by muse, mutect2, varscan2
- LAMA5 | c.4673G>T p.G1558V | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53367687; called by muse, mutect2, varscan2
- LRFN5 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53267765, COSV99982616; called by muse, mutect2, varscan2
- MAST3 | c.2603G>A p.G868D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV53224796; called by muse, mutect2, varscan2
- OR10A7 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.239); catalogued as rs376446425, COSV58278801; called by muse, mutect2, varscan2
- OR10AD1 | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59612918; called by muse, mutect2, varscan2
- OR10J1 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71129350; called by muse, mutect2, varscan2
- OR52J3 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs577465287, COSV66746663; called by muse, mutect2, varscan2
- OR5AR1 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 46/226 reads (20%) | catalogued as COSV57254793; called by muse, mutect2, varscan2
- OVCH1 | c.2574dup p.P859Sfs*10 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | catalogued as rs762411340; called by mutect2, pindel
- OXCT1 | c.1497G>C p.Q499H | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52169578, COSV52174918; called by muse, mutect2, varscan2
- PDE1A | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV59521568; called by muse, mutect2, varscan2
- PHTF1 | c.505_506del p.V169Kfs*3 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs1335621608; called by mutect2, varscan2
- PLD5 | c.533C>T p.S178L (on ENST00000442594; = p.S116L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs762589861, COSV59133651; called by muse, mutect2
- POLE | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV57686736; called by muse, mutect2, varscan2
- RBMXL2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs776881323, COSV60981212; called by muse, mutect2, varscan2
- RIPPLY3 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV61567006; called by muse, mutect2, varscan2
- RNF26 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 95/113 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs150176910; called by muse, mutect2, varscan2
- RP1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1178043951, COSV55111774; called by muse, mutect2, varscan2
- SBF1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 85/123 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV62369612; called by muse, mutect2, varscan2
- SCN11A | c.4846G>A p.D1616N | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV56575145; called by muse, mutect2, varscan2
- SIK2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 45/58 reads (78%) | catalogued as COSV59254877; called by muse, mutect2, varscan2
- SLC16A13 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769785610, COSV57274109; called by muse, mutect2, varscan2
- SLC17A6 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV54139454; called by muse, mutect2, varscan2
- TAS2R4 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as rs758615597, COSV56093965; called by muse, mutect2, varscan2
- TCEA2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 51/58 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1170302218, COSV58657350; called by muse, mutect2, varscan2
- TECRL | c.811T>G p.L271V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV67089391; called by muse, mutect2, varscan2
- TENT5A | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs747135448, COSV60788175; called by muse, mutect2, varscan2
- TEP1 | c.1796C>A p.T599N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV52997169; called by muse, mutect2, varscan2
- TIMP3 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 54/75 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56661663; called by muse, mutect2, varscan2
- TOR1A | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1456730486, COSV61029568; called by muse, mutect2
- TOX2 | c.1399C>A p.P467T (on ENST00000358131 / NM_001098798.2; = p.P443T on NM_032883.3) | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.224); catalogued as COSV57892385; called by muse, mutect2, varscan2
- TRIML2 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58718445; called by muse, mutect2, varscan2
- UBQLN4 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV64150037; called by muse, mutect2, varscan2
- ZNF831 | c.3681C>A p.S1227R | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64043492; called by muse, mutect2, varscan2
- ADCY2 | c.1826_1827del p.L609Hfs*94 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | called by pindel, varscan2
- HSPA6 | c.233_234insA p.K79Qfs*76 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | called by mutect2, pindel*, varscan2
- KHDC4 | c.1708_1709del p.D570Ffs*3 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- LPP | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- LPP | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NOL4L | c.369_370del p.V124Efs*26 | Frame Shift Del (DEL) | VAF 98/374 reads (26%) | called by mutect2, pindel, varscan2
- RP1 | c.5953A>T p.I1985F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by mutect2, varscan2
- TM9SF3 | c.1323dup p.W442Mfs*23 | Frame Shift Ins (INS) | VAF 72/177 reads (41%) | called by mutect2, pindel, varscan2
- WBP4 | c.101_104del p.K34Ifs*39 | Frame Shift Del (DEL) | VAF 29/55 reads (53%) | called by mutect2, pindel, varscan2
- ACADS | c.714G>A p.T238= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs771881207, COSV54369846; called by muse, mutect2, varscan2
- ADAMTS10 | c.372C>T p.Y124= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs138572540; called by muse, mutect2, varscan2
- B4GALT2 | c.693C>T p.G231= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs373628559; called by muse, mutect2, varscan2
- CHFR | c.849C>T p.T283= (on ENST00000432561 / NM_001161345.1; = p.T242= on NM_018223.2) | Silent (SNP) | VAF 49/78 reads (63%) | catalogued as rs747517165, COSV57176783; called by muse, mutect2, varscan2
- DSC1 | c.2586A>T p.V862= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs771526982, COSV57149371; called by muse, mutect2, varscan2
- FBXW2 | c.1152C>T p.N384= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV61597715; called by muse, mutect2, varscan2
- FOXO3 | c.1263G>A p.S421= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as rs777494067, COSV59630194; called by muse, mutect2, varscan2
- GJA8 | c.129C>T p.F43= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs267598000, COSV53787764; called by muse, mutect2, varscan2
- GLI2 | c.1398C>A p.P466= (on ENST00000361492 / NM_001374353.1; = p.P483= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/121 reads (59%) | catalogued as COSV58048160; called by muse, mutect2, varscan2
- KIF26B | c.4065C>A p.A1355= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV63647678; called by muse, mutect2, varscan2
- QPCTL | c.9C>G p.S3= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV50004524; called by muse, mutect2, varscan2
- SH3BP4 | c.1089G>A p.P363= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs377177002, COSV60646006; called by muse, mutect2, varscan2
- SORL1 | c.2496G>A p.E832= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV52759534, COSV99495435; called by muse, mutect2, varscan2
- UCKL1 | c.1368G>T p.V456= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV62403494; called by muse, mutect2, varscan2
- ZNF568 | c.1134G>A p.T378= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as rs1453512553, COSV61742486; called by muse, mutect2, varscan2
- GRM1 | c.2661-7308G>A | Intron (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
- MIR217 | n.98G>T | RNA (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
